Surgical pathology report (de-identified scan), TCGA case TCGA-EI-6508, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-EI-6508-01A (Primary Tumor).

Examination: Histopathological examination

Material: Multiple organ resection – segment of the large intestine

TCGA – EI – 6508

Physician in charge:

Material collected on: Material received on

Expected time of examination:

Clinical diagnosis:

Examination performed on

Macroscopic description:

10 cm length of the large intestine with mesorectum fat tissue of 2 cm in thickness. A cauliflower-shaped tumour sized 5 x 4 x 1.4 cm found in the mucosa. The lesion covers 80% of the intestine circumference, located 2.5 cm from the proximal cut end and 1 cm from the distal cut end. Minimum side margin is 1,2 cm.

Microscopic description:

Adenocarcinoma tubuloapapillare (G1). Infiltratio carcinomatosa tunicae muscularis propriae et telae adiposae mesorecti. Intestine ends free of neoplastic lesions. Metastases carcinomatosae in lymphonodo (No I/XV).

Histopathological diagnosis:

Adenocarcinoma tubulopapillare (G1; Dukes C, Astler-Coller C2; pT3; pN1a, R0).

Tubulopapillary adenocarcinoma of the colon

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file ae168cf2-e0f6-4496-998e-9dbb6fc47ce0 (TCGA-EI-6508.5924998A-33F5-42B7-B876-2080713A44C3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).